National Lung Screening Trial (NLST) participant 123009 — screening results and CT findings
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 56 years; Gender: female; Race: White; Cigarette smoking status at randomisation: former smoker (to be eligible, former smokers had quit within the previous 15 years); Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 0): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 120 mA, display field of view 33 cm, reconstruction filter Siemens, other.
- T1 (day 402): Positive, other. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 120 mA, 30 effective mAs, display field of view 26 cm, reconstruction filter Siemens B30 / Siemens B50F.
- T2 (day 933): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 90 mA, 30 effective mAs, display field of view 26 cm, reconstruction filter Siemens B30 / Siemens B50F.

Abnormalities recorded by the reading radiologist on the CT screens (11 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 4 mm, longest perpendicular diameter 4 mm; margins spiculated (stellate); predominant attenuation soft tissue; greatest diameter on CT slice 238.
- T0 abnormality 2: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T0 abnormality 3: Emphysema.
- T0 abnormality 4: Significant cardiovascular abnormality.
- T0 abnormality 5: Other minor abnormality noted.
- T1 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right upper lobe; longest diameter 5 mm, longest perpendicular diameter 3 mm; margins spiculated (stellate); predominant attenuation soft tissue; greatest diameter on CT slice 81; pre-existing on earlier images (earliest visible day 0); no interval growth; no suspicious change in attenuation.
- T1 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left upper lobe; longest diameter 5 mm, longest perpendicular diameter 3 mm; margins spiculated (stellate); predominant attenuation soft tissue; greatest diameter on CT slice 81; pre-existing on earlier images (earliest visible day 0); interval growth; no suspicious change in attenuation.
- T1 abnormality 3: Emphysema.
- T2 abnormality 1: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T2 abnormality 2: Emphysema.
- T2 abnormality 3: Other minor abnormality noted.

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 2,590.
